Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A6AW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A6AW-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

[Redacted Patient Information]

(Age:

M

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

[Redacted Accession #]

INPATIENT

Clinical Diagnosis & History:

Bladder carcinoma.

Specimens Submitted:

- 1: SP: Right pelvic lymph nodes, excision (fs)
- 2: SP: Perivesical tissue, excision
- 3: SP: Right pelvic lymph nodes, excision
- 4: SP: Left pelvic lymph nodes, excision
- 5: SP: Bladder, prostate, seminal vesicles, urethra, perivesical tissue and lymph nodes, radical cystoprostatectomy
- 6: SP: Left pelvic lymph nodes, excision
- 7: SP: Right pelvic lymph nodes, excision
- 8: SP: Left vas deferens, excision
- 9: SP: Lipoma of left spermatic cord
- 10: SP: Right vas deferens, excision
- 11: SP: Urachus, excision
- 12: SP: Distal right ureter, excision

*ICD-8:31 NOS
8120/3
Site cscf Bladder trigone C67.0
path Bladder, ureteric or urei
C67.6
QW 6/18/13*

DIAGNOSIS:

1. SP: Right pelvic lymph nodes, excision (fs):

Lymph Nodes:

Not involved

Number of nodes examined:7

2. SP: Perivesical tissue, excision:

- Benign fibroadipose tissue.

3. SP: Right pelvic lymph nodes, excision:

Lymph Nodes:

Not involved

Number of nodes examined:3

4. SP: Left pelvic lymph nodes, excision:

Lymph Nodes:

Not involved

Number of nodes examined:2

5. SP: Bladder, prostate, seminal vesicles, urethra, perivesical tissue and lymph nodes, radical cystoprostatectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

Pattern of growth of the Non-Invasive component:
Flat (in situ carcinoma)

Pattern of growth of the Invasive component:
Infiltrating

Tumor Multicentricity:
Not identified

Bladder Local Invasion:
Superficial half of muscularis propria

Extravesical Tumor Extension:
Ureters uninvolved.

Vascular Invasion:
Not identified

Perineural Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Mucosa:
Exhibiting granulomatous cystitis

Prostate:
Nodular hyperplasia

Seminal Vesicles:
Not involved

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT2a (Invades superficial half of muscularis propria)
PR0 (No involvement of prostate)

6. SP: Left pelvic lymph nodes, excision:

Lymph Nodes:
Number of nodes examined:13
Number of metastatic nodes:0

7. SP: Right pelvic lymph nodes, excision:

Lymph Nodes:
Number of nodes examined:2
Number of metastatic nodes:0

8. Left vas deferens, excision:

- Benign vas deferens.

9. Lipoma of left spermatic cord; excision:

- Benign fibroadipose tissue.

10. Right vas deferens, excision:

- Benign vas deferens.

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

11. Urachus; excision:

- Benign fibroadipose tissue.

12. Distal right ureter; excision:

- Benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for intraoperative consultation, labeled "right pelvic lymph nodes " and consists of two pink tan fatty lymph nodes (1.5 and 6.5 cm in greatest dimension) which are bisected and submitted for frozen section (FSA: one lymph node; FSB-FSD: one trisected lymph node). Possible smaller lymph nodes (0.5-0.8 cm) are identified and submitted for paraffin sections.

Summary of sections:

FSCA - frozen section control
FSCB - frozen section control
FSCC - frozen section control
FSCD - frozen section control
LN - lymph nodes

2). The specimen is received fresh, labeled "perivesical tissue, fresh and sterile" and consists of a single ovoid portion of pink-tan to yellow-tan, lobulated fibroadipose tissue measuring 7 x 4 x 1.2 cm with no lymph nodes grossly identified. Representative sections are submitted.

Summary of sections:

U -- undesignated

3). The specimen is received fresh, labeled "right pelvic lymph nodes, fresh and sterile" and consists of three pink tan firm lymph nodes ranging from 1 to 3.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph node
TLN -- trisected lymph node
QLN -- quadrisected lymph node

4). The specimen is received fresh, labeled "left pelvic lymph nodes, fresh and sterile" and consists of two pink tan firm lymph nodes measuring 1.9 and 2.9 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph node
BLN -- bisected lymph node

[page 4 of 7]
5) The specimen is received fresh labeled, "Bladder, prostate, seminal vesicles, urethra, perivesical tissue and lymph nodes". It consists of a cystoprostatectomy specimen measuring 18.5 cm from superior to inferior, 7.5 cm laterally and 5.0 cm from anterior to posterior. The left prostate is inked blue and the right prostate is inked green and the remainder of the specimen is inked magenta. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal two polypoid tumors measuring 2.5 x 1.9 x 1.2 cm (t1) and 1.4 x 1.3 x 0.8 cm (t2). T1 is grossly situated adjacent to the opening of the prostatic urethra, 0.6 cm from the right ureter. T2 is grossly situated on the left side and is partially occluding the left ureteral orifice. Both ureters are probe patent measuring 0.6 (right) and 1.1 cm (left) in maximum diameter. The lesion is sectioned to reveal no invasion beyond the base of the polyp. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is ulceration and congestion at the trigone. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal multiple BPH nodules. Representative sections are submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted.

Summary of sections:

UTHM -- urethral margin
RUM-- right ureter margin
LUM -- left ureter margin
T1RUO -- right ureter orifice
T2LUO-- entire T2 and entire left ureteral orifice
LP -- left posterior wall
LA -- left anterior wall
RP -- right posterior wall
RA-- right anterior wall
TRI -- trigone
DOM-- dome
F -- perivesical fat
RSV -- right seminal vesicle
LSV -- left seminal vesicle
RAP -- right apex prostate
LAP -- left apex prostate
RAM -- right anterior mid prostate
RPM -- right posterior mid prostate
LAM -- left anterior mid prostate
LPM -- left posterior mid prostate
RAB -- right anterior base prostate
RPB -- right posterior base prostate
LAB -- left anterior base prostate
LPB -- left posterior base prostate

6). The specimen is received fresh, labeled "left pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 3.9 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

7). The specimen is received fresh, labeled "right pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.5 cm in greatest dimension. All identified lymph nodes are submitted. (The entire specimen is submitted)

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

8). The specimen is received in formalin, labeled "Left vas deferens" and consists of an unoriented segment of pink-tan tubular tissue measuring 8.7 cm in length and 0.3 cm in maximum diameter, with scant yellow-tan soft tissue attached. On cut section, a pinpoint lumen is identified. No discrete abnormalities are grossly noted. Representative sections of the specimen are submitted.

Summary of sections:

E - ends
C - center

9). The specimen is received in formalin, labeled "Lipoma of left spermatic cord" and consists of a formed mass of yellow-tan lobulated soft tissue measuring 6.2 x 3 x 0.9 cm. The external surface covered by a thin transparent membrane. Sectioning reveals yellow-tan lobulated and grossly unremarkable soft tissue. Representative sections are submitted.

Summary of sections:

U-undesignated

10). The specimen is received in formalin, labeled "Right vas deferens" and consists of an unoriented segment of pink-tan tubular tissue measuring 4.7 cm in length and 0.3 cm in maximum diameter, with scant yellow-tan soft tissue attached. On cut section, a pinpoint lumen is identified. No discrete abnormalities are grossly noted. Representative sections of the specimen are submitted.

Summary of sections:

E - ends
C - center

11). The specimen is received in formalin, labeled "Urachus" and consists of a piece of focally hemorrhagic fatty tissue measuring 7.5 x 2.8 x 1.0 cm. Sectioning reveals no definitive urachus. The specimen is serially sectioned from end to end and is entirely submitted.

Summary of sections:

SS – serial sections

12). The specimen is received in formalin, labeled "Distal right ureter" and consists of a segment of ureter measuring 2.9 cm in length and 0.5 cm in maximum diameter, with attached adipose tissue. A clip is identified at one end, which marks the proximal margin and is inked black. The specimen is serially sectioned to reveal a patent stellate lumen with no abnormalities grossly noted. The specimen is serially sectioned from the unclipped to clipped end, and is entirely submitted.

Summary of sections:

C-clipped end, margin

SS-serial sections clipped to opposite unclipped end

OE – opposite unclipped end

Summary of Sections:

Part 1: SP: Right pelvic lymph nodes, excision (fs)

Block	Sect. Site	PCs
1	fsca	1
1	fscb	1
1	fscd	1
1	fscd	1
1	ln	1

Part 2: SP: Perivesical tissue, excision

Block	Sect. Site	PCs
-------	------------	-----

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

2 U 20

Part 3: SP: Right pelvic lymph nodes, excision

Block	Sect. Site	PCs
1	LN	1
4	QLN	4
3	TLN	3

Part 4: SP: Left pelvic lymph nodes, excision

Block	Sect. Site	PCs
2	BLN	2
1	LN	1

Part 5: SP: Bladder, prostate, seminal vesicles, urethra, perivesical tissue and lymph nodes, radical cystoprostatectomy

Block	Sect. Site	PCs
1	dom	1
1	f	1
1	la	1
1	lab	1
1	lam	1
1	lap	1
1	lp	1
1	lpb	1
1	lpm	1
1	lsv	1
1	lum	1
1	ra	1
1	rab	1
1	ram	1
1	rap	1
1	rp	1
1	rpb	1
1	rpm	1
1	rsv	1
1	rum	1
5	t1ruo	5
5	t2luo	5
1	tri	1
1	uthm	1

Part 6: SP: Left pelvic lymph nodes, excision

Block	Sect. Site	PCs
4	bln	4
4	lgn	4
3	ln	3

Part 7: SP: Right pelvic lymph nodes, excision

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Part 8: SP: Left vas deferens, excision

Block	Sect. Site	PCs
1	c	1

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

1 e 1

Part 9: SP: Lipoma of left spermatic cord

Block	Sect. Site	PCs
3	ss	3

Part 10: SP: Right vas deferens, excision

Block	Sect. Site	PCs
1	c	1
1	e	1

Part 11: SP: Urachus, excision

Block	Sect. Site	PCs
6	ss	6

Part 12: SP: Distal right ureter, excision

Block	Sect. Site	PCs
1	c	1
1	oe	1
1	ss	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1A-D. FROZEN SECTION DIAGNOSIS: SP: RIGHT PELVIC LYMPH NODES (FS): NEGATIVE LYMPH NODES
PERMANENT DIAGNOSIS: SAME.

,MD

Source: NCI Genomic Data Commons file 2cad6db7-4bb7-4b99-9b46-a33d44afc35c (TCGA-DK-A6AW.FFC32668-B801-48EB-BBAC-0E624AEED12D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).